Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8335, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8335-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

13.6 cm left renal mass. Radical nephrectomy specimen.

Specimens Submitted:

1: SP: Kidney, adrenal gland and enbloc lymph node dissection, left, radical nephrectomy

2: SP: Lymph node, para-aortic, excision

DIAGNOSIS:

1. SP: Kidney, adrenal gland and enbloc lymph node dissection, left, radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Chromophobe type

Fuhrman Nuclear Grade:

N/A

Tumor Size:

Greatest diameter is 13.0 cm.

The tumor is associated with extensive necrosis

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Vascular invasion of small to medium sized vessels is present

Surgical Margins:

Free of tumor

Unremarkable ureter

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

The tumor approaches but does not invade the adrenal gland

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

2. SP: Lymph node, para-aortic, excision

Lymph Nodes:

Not involved

Number of nodes examined:8

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1) The specimen is received fresh, labeled "Left kidney, adrenal gland and en bloc lymph node dissection". It consists of a radical nephrectomy specimen composed of kidney and perirenal fat measuring 30.0 x 12.0 x 10.0 cm and weighing 2252 gm. After bivalving the specimen a kidney measuring 21.0 x 11.0 x 8.8 cm reveals at the upper pole a 13.0 x 12.0 x 10.0 cm partially necrotic yellow-tan centrally scarred tumor. The tumor appears to be well-encapsulated but pushes into the perirenal fat. Gross no evidence of capsule breakthrough is noted. Tumor appears to also deform and abut the calyceal pelvic system with no breakthrough. Serial sectioning of the tumor reveals a hemorrhagic multiple variegated yellow-tan and red tumor with a central area of scarring. Sectioning through the hilar fat reveals multiple lymph nodes. A 14.3 x 0.5 cm attached ureter is identified which probe patent and negative for lesions. The ureteral margin is shaved and submitted together with the vascular margins which appear also grossly negative. Sectioning through the perirenal fat reveals a 3.8 x 2.8 x 1.2 cm adrenal gland which abuts the superior surface of the tumor. The tumor appears not to invade the adrenal gland. Gross photographs are taken and TPS is taken.

Summary of Sections:

MAR – vascular and ureteral margins

LN - lymph nodes of renal hilum

TNCP - tumor with renal capsule

TMSIN – tumor with renal sinus

TM – tumor

TMPL – tumor and pelvis

ADR – adrenal gland with tumor abutting

NK – normal kidney

TMKI – tumor with adjacent normal kidney

2). The specimen is received in formalin labeled, "Para-aortic lymph node", and consists of five possible lymph nodes measuring 4.5 x 3 x 1.6 cm in aggregate. Lymph nodes are entirely submitted.

Summary of sections:

TLN– trisected lymph node

BLN-bisected lymph node

LN-whole lymph nodes

Summary of Sections:

Part 1: SP: Kidney, adrenal gland and enbloc lymph node dissection, left, radical nephrectomy (tl)

Block	Sect. Site	PCs
4	adr	4
8	ln	8

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

1	mar	1
2	nk	2
6	tm	6
8	tmcap	8
1	tmki	1
1	tmpel	1
3	tmsin	3

Part 2: SP: Lymph node, para-aortic, excision

Block	Sect. Site	PCs
2	bln	2
3	lln	3
1	ln	1

Source: NCI Genomic Data Commons file 79958550-8d76-44aa-a8b2-59d2f7a20c98 (TCGA-KL-8335.C0288DC5-8075-4D1C-A0D4-25C8A72EEAF4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).